Somatic mutation profile of tumor specimen TCGA-10-0930-01A (aliquot TCGA-10-0930-01A-02W-0421-09) from TCGA case TCGA-10-0930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.5 years (25,737 days).
Specimen TCGA-10-0930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90e93e85-f594-4dae-83de-8bc299b159a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0930-11A (Solid Tissue Normal), aliquot TCGA-10-0930-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dd87e1c-db24-4c1c-a1f0-7cf045011b4c

The open-access MAF lists 157 somatic variants for this specimen: 130 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 24, Splice Site 8, Nonsense Mutation 5, Frame Shift Del 5, In Frame Del 4, Nonstop Mutation 2, Frame Shift Ins 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.5838+1G>T p.X1946_splice | Splice Site (SNP) | VAF 34/44 reads (77%) | catalogued as rs1559234260, COSV55099345; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.3383C>G p.T1128R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.351); catalogued as COSV58140547; called by muse, mutect2, varscan2
- ADAMTS16 | c.1978T>A p.F660I | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99940307; called by muse, mutect2, varscan2
- ALPK2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV64494891; called by muse, varscan2
- ARID1A | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 180/277 reads (65%) | catalogued as COSV100250329, COSV61383603; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1164265674, COSV63438510; called by muse, mutect2, varscan2
- ATN1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV57547240; called by muse, mutect2, varscan2
- BRI3BP | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); catalogued as COSV58296765; called by muse, mutect2, varscan2
- BRWD1 | c.1185G>T p.W395C | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60899855; called by muse, mutect2, varscan2
- BTBD1 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV55603889, COSV55604236; called by muse, mutect2, varscan2
- BUB1B | c.2460T>A p.D820E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99806633; called by muse, mutect2, varscan2
- CACNA1D | c.2080G>A p.A694T (on ENST00000350061 / NM_001128840.3; = p.A714T on NM_000720.4) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55456669; called by muse, mutect2, varscan2
- CAGE1 | c.1303G>T p.V435L (on ENST00000512086; = p.V299L on NM_205864.3) | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57079368; called by muse, mutect2, varscan2
- CCDC80 | c.1966A>C p.K656Q | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV52818623; called by muse, mutect2, varscan2
- CCR8 | c.696C>G p.N232K | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV58337634; called by muse, mutect2, varscan2
- CDH19 | c.1523A>T p.N508I | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV50967127; called by muse, mutect2, varscan2
- CELF5 | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV53013435; called by muse, mutect2, varscan2
- CEP290 | c.6473T>C p.L2158S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV58353970; called by muse, mutect2, varscan2
- CEP89 | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs776618483, COSV59866081; called by muse, mutect2, varscan2
- CIDEA | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV57599643; called by muse, mutect2, varscan2
- CLEC14A | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60563506; called by muse, varscan2
- COL12A1 | c.5547C>G p.N1849K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59401564; called by muse, mutect2, varscan2
- COL21A1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV55172244; called by muse, mutect2, varscan2
- CTAGE15 | c.1446A>C p.E482D | Missense Mutation (SNP) | VAF 50/305 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV69482091; called by muse, mutect2, varscan2
- DAND5 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57684463; called by muse, mutect2, varscan2
- DCDC1 | c.2033G>T p.S678I | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV100662845; called by muse, mutect2
- DHCR7 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62795977; called by muse, mutect2, varscan2
- DIS3L | c.2201+2T>G p.X734_splice (on ENST00000319212 / NM_001143688.3; = p.X651_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100055618, COSV59913449; called by muse, mutect2, varscan2
- DMD | c.5320G>T p.G1774* | Nonsense Mutation (SNP) | VAF 61/99 reads (62%) | catalogued as COSV63775855; called by muse, mutect2, varscan2
- DMD | c.1346T>C p.L449S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD073604; called by muse, mutect2
- DNAH3 | c.2916A>C p.E972D | Missense Mutation (SNP) | VAF 110/505 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV54536700; called by muse, mutect2, varscan2
- EFHB | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 196/367 reads (53%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV55550904; called by muse, mutect2, varscan2
- EGR1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53520506; called by muse, mutect2, varscan2
- ERVFRD-1 | c.221T>G p.I74S | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV65369603; called by muse, mutect2, varscan2
- FAT1 | c.13178C>A p.P4393H | Missense Mutation (SNP) | VAF 143/218 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV71675174; called by muse, mutect2, varscan2
- FCGR1A | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as rs1349287179, COSV64985829; called by muse, mutect2, varscan2
- FNDC5 | c.421A>T p.M141L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV65105954; called by muse, mutect2, varscan2
- FOLR1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 184/419 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56616634, COSV56617250; called by muse, mutect2, varscan2
- FRAS1 | c.3119A>T p.Y1040F | Missense Mutation (SNP) | VAF 98/148 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV53629292; called by muse, mutect2, varscan2
- FRMPD3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750463805, COSV52188915; called by muse, mutect2, varscan2
- GAPVD1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV52925435; called by muse, mutect2, varscan2
- GIMAP6 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs779061760, COSV61034145; called by muse, mutect2, varscan2
- GRIP1 | c.2081T>C p.F694S (on ENST00000359742 / NM_001379345.1; = p.F642S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99668379; called by muse, mutect2
- GRM7 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63130235, COSV63156217; called by muse, mutect2, varscan2
- HNRNPA1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV52937826; called by muse, mutect2, varscan2
- HSP90AA1 | c.530-2A>T p.X177_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99355085; called by mutect2, varscan2
- IRF2 | c.172T>C p.W58R | Missense Mutation (SNP) | VAF 79/130 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66929998; called by muse, mutect2, varscan2
- ITK | c.1514+1G>A p.X505_splice | Splice Site (SNP) | VAF 29/131 reads (22%) | catalogued as COSV101439655; called by muse, mutect2, varscan2
- KCNQ5 | c.1051G>C p.A351P | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV100573582, COSV59672599; called by muse, mutect2, varscan2
- KNTC1 | c.1616G>T p.W539L | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199501312, COSV61082162; called by muse, mutect2, varscan2
- KRIT1 | c.1738A>G p.N580D | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.226); catalogued as COSV60667081, COSV60669373; called by muse, mutect2, varscan2
- KY | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs750351662, COSV71018091; called by muse, mutect2, varscan2
- LILRB4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV54407036; called by muse, mutect2, varscan2
- LRIF1 | c.2146C>G p.Q716E | Missense Mutation (SNP) | VAF 115/675 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV63897995; called by muse, mutect2, varscan2
- LRP1B | c.12487A>G p.I4163V | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs757814963, COSV101253674; called by muse, mutect2, varscan2
- LRRC7 | c.4205T>A p.V1402E (on ENST00000651989 / NM_001370785.2; = p.V1322E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50447427, COSV50521400; called by muse, mutect2, varscan2
- LRRC71 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61656521; called by muse, mutect2, varscan2
- MAN2A2 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as COSV64639136; called by muse, mutect2, varscan2
- MAST2 | c.5397G>C p.*1799Yext*? | Nonstop Mutation (SNP) | VAF 45/59 reads (76%) | catalogued as COSV53109566; called by muse, mutect2, varscan2
- MED12 | c.4524C>G p.H1508Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61348513; called by muse, mutect2, varscan2
- MED12L | c.2272A>G p.K758E | Missense Mutation (SNP) | VAF 46/387 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV56388033; called by muse, mutect2, varscan2
- MMP8 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52633606, COSV52633919; called by muse, mutect2, varscan2
- MSRB1 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51907601; called by muse, mutect2, varscan2
- MTO1 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV64774428; called by muse, mutect2, varscan2
- MTOR | c.3518C>G p.A1173G | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100815790; called by muse, mutect2, varscan2
- MTUS2 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV70918815; called by muse, mutect2, varscan2
- MYH8 | c.3640C>A p.Q1214K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV67969167; called by muse, mutect2, varscan2
- MYOM1 | c.4561C>G p.P1521A | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55296651; called by muse, mutect2, varscan2
- NAF1 | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV56804557, COSV56805149; called by muse, mutect2, varscan2
- NCAN | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564199075, COSV53054744; called by muse, mutect2, varscan2
- NCKAP1L | c.3047C>G p.S1016C | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.75); catalogued as COSV53209854; called by muse, mutect2, varscan2
- NPC1 | c.2993T>G p.F998C | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52581277; called by muse, mutect2, varscan2
- NPPB | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV64687745; called by muse, mutect2, varscan2
- NSUN6 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV66034284; called by muse, mutect2, varscan2
- NUGGC | c.1955A>T p.K652M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58437161; called by muse, mutect2, varscan2
- OR4C46 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60220502; called by muse, mutect2, varscan2
- OR5D16 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV65721908, COSV65722471; called by muse, mutect2, varscan2
- OTUD4 | c.3115T>G p.S1039A (on ENST00000447906 / NM_001366057.1; = p.S974A on NM_001102653.1) | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV71382075; called by muse, varscan2
- PALM2AKAP2 | c.847A>G p.M283V (on ENST00000374531 / NM_001037293.2; = p.M315V on NM_053016.6) | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV57127206; called by muse, mutect2, varscan2
- PHOX2B | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56930671; called by muse, mutect2, varscan2
- PKHD1 | c.2134G>C p.V712L | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144455663, COSV61880538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCD4 | c.1303A>G p.K435E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68843097; called by muse, mutect2, varscan2
- PLEC | c.10316G>T p.R3439M (on ENST00000322810 / NM_201380.4; = p.R3329M on NM_000445.5) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV59665932; called by muse, mutect2, varscan2
- POGLUT1 | c.639-1G>C p.X213_splice | Splice Site (SNP) | VAF 44/237 reads (19%) | catalogued as COSV55157564; called by muse, mutect2, varscan2
- PREP | c.1016-2A>C p.X339_splice (on ENST00000369110; = p.X405_splice on NM_002726.5) | Splice Site (SNP) | VAF 49/150 reads (33%) | catalogued as COSV64871152; called by muse, mutect2, varscan2
- PSMC3 | c.619A>C p.N207H | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV54081863; called by muse, mutect2, varscan2
- PTEN | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 131/232 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64301465, COSV64302177; called by mutect2, varscan2
- RBL1 | c.2382G>C p.K794N | Missense Mutation (SNP) | VAF 82/499 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100726844, COSV60331526; called by muse, mutect2, varscan2
- RHOT1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV61717277; called by muse, mutect2, varscan2
- RUFY1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV60162224; called by muse, mutect2, varscan2
- SALL1 | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV51761209; called by muse, mutect2
- SCN10A | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV71861690; called by muse, mutect2, varscan2
- SH2B3 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV57985058; called by muse, mutect2, varscan2
- SHKBP1 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52541894; called by muse, mutect2, varscan2
- SLC6A3 | c.1333C>G p.R445G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM143023, COSV54361620, COSV54366940; called by muse, varscan2
- SLC9C1 | c.700A>T p.M234L | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59890526; called by muse, mutect2, varscan2
- SLIT1 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV56594305; called by muse, mutect2, varscan2
- SNAP91 | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.404); catalogued as COSV52128765; called by muse, mutect2, varscan2
- SS18L1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59212061; called by muse, mutect2
- STK38L | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV66522360; called by muse, mutect2, varscan2
- TAF5 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV60857534; called by muse, mutect2, varscan2
- TBC1D32 | c.3772T>A p.*1258Kext*7 | Nonstop Mutation (SNP) | VAF 87/214 reads (41%) | catalogued as COSV51548824; called by muse, mutect2, varscan2
- TGFBR3 | c.2300G>C p.S767T | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV53028705, COSV53028718; called by muse, mutect2, varscan2
- THOC7 | c.546A>T p.E182D | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55734014; called by muse, varscan2
- TPTE2 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV55025139; called by muse, mutect2, varscan2
- USP24 | c.7261T>C p.Y2421H | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53773217; called by muse, mutect2, varscan2
- WRN | c.1893T>G p.I631M | Missense Mutation (SNP) | VAF 71/106 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV53303946; called by muse, mutect2, varscan2
- Z83844.2 | c.1587G>C p.E529D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); catalogued as COSV53216936; called by muse, mutect2, varscan2
- ZNF197 | c.83C>A p.T28N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as COSV60361248; called by muse, mutect2, varscan2
- ZNF236 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 77/120 reads (64%) | catalogued as COSV99469374; called by muse, mutect2, varscan2
- C15orf39 | c.580dup p.V194Gfs*4 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by pindel, varscan2
- CCDC28A | c.477+1del p.X159_splice | Splice Site (DEL) | VAF 63/178 reads (35%) | called by mutect2, pindel, varscan2
- COL5A2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX52 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 98/141 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- HYDIN | c.1039T>C p.Y347H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNIP3 | c.724-11_734del p.X242_splice | Splice Site (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- LAS1L | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.19); called by muse, mutect2
- MAGEE2 | c.1384_1395del p.E462_L465del | In Frame Del (DEL) | VAF 87/214 reads (41%) | called by mutect2, pindel, varscan2
- OR4F5 | c.672T>G p.D224E | Missense Mutation (SNP) | VAF 55/711 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5T1 | c.569_573del p.F190* | Frame Shift Del (DEL) | VAF 84/560 reads (15%) | called by mutect2, pindel, varscan2
- PIAS1 | c.848_860del p.Y283Cfs*16 | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | called by mutect2, pindel*
- RPF2 | c.477_485del p.K160_L162del | In Frame Del (DEL) | VAF 62/153 reads (41%) | called by mutect2, pindel, varscan2
- S1PR2 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- SHBG | c.522dup p.L175Afs*39 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- SLC6A17 | c.1532_1543del p.F511_R514del | In Frame Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.561del p.I188* | Frame Shift Del (DEL) | VAF 66/218 reads (30%) | called by mutect2, pindel, varscan2
- TPTE2 | c.957C>G p.H319Q (on ENST00000400230 / NM_199254.2; = p.H242Q on NM_130785.3) | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBN2 | c.1092_1095delinsT p.L365del | In Frame Del (DEL) | VAF 19/94 reads (20%) | called by pindel, varscan2*
- UBR1 | c.4651_4673del p.F1551Gfs*31 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- ZNF518B | c.3170_3188del p.R1057Lfs*14 | Frame Shift Del (DEL) | VAF 43/82 reads (52%) | called by mutect2, pindel, varscan2
- CDK5R1 | c.522C>T p.P174= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as COSV55577379; called by muse, mutect2, varscan2
- CYP2C9 | c.939G>A p.L313= | Silent (SNP) | VAF 194/475 reads (41%) | catalogued as COSV53250862; called by muse, mutect2, varscan2
- DCAF5 | c.1455C>A p.P485= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58461704; called by muse, mutect2, varscan2
- DHX30 | c.1974G>A p.L658= (on ENST00000445061 / NM_138615.3; = p.L619= on NM_014966.3) | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as COSV53140495; called by muse, mutect2, varscan2
- EHD4 | c.399C>T p.N133= | Silent (SNP) | VAF 72/125 reads (58%) | catalogued as rs748481753, COSV55006082; called by muse, mutect2, varscan2
- EPHA6 | c.498A>G p.T166= | Silent (SNP) | VAF 118/340 reads (35%) | catalogued as COSV67583788; called by muse, mutect2, varscan2
- GON4L | c.5424G>A p.L1808= | Silent (SNP) | VAF 71/170 reads (42%) | catalogued as rs756975667, COSV55198490; called by muse, mutect2, varscan2
- GPX2 | c.513C>G p.R171= | Silent (SNP) | VAF 68/369 reads (18%) | catalogued as COSV63036521; called by muse, mutect2, varscan2
- LDB3 | c.723C>T p.S241= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs200580597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.12486G>A p.L4162= | Silent (SNP) | VAF 130/412 reads (32%) | catalogued as COSV101253386, COSV101253676; called by muse, mutect2, varscan2
- LVRN | c.129C>T p.V43= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV63497816; called by muse, mutect2, varscan2
- MAL2 | c.378G>C p.L126= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV52662126; called by muse, mutect2, varscan2
- MARCO | c.453C>G p.G151= | Silent (SNP) | VAF 130/453 reads (29%) | catalogued as COSV59056464; called by muse, mutect2, varscan2
- MC5R | c.657C>T p.I219= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs747840339, COSV61255214; called by muse, mutect2, varscan2
- NPC1L1 | c.3447C>T p.P1149= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV56928016; called by muse, mutect2, varscan2
- OR10H4 | c.486G>A p.T162= | Silent (SNP) | VAF 105/208 reads (50%) | catalogued as rs201781055; called by muse, mutect2, varscan2
- PARP9 | c.99C>A p.I33= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs1191014369, COSV64451314; called by muse, mutect2
- PDE8A | c.363G>A p.L121= | Silent (SNP) | VAF 66/187 reads (35%) | catalogued as COSV59638935; called by muse, mutect2, varscan2
- PFAS | c.399G>A p.P133= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs778367280, COSV58978510; called by muse, mutect2, varscan2
- PGA3 | c.201C>A p.P67= | Silent (SNP) | VAF 120/185 reads (65%) | catalogued as rs527696591, COSV100337369, COSV57711923; called by muse, mutect2, varscan2
- PNPLA6 | c.2571C>T p.D857= (on ENST00000414982 / NM_001166111.2; = p.D809= on NM_006702.5) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs771821425, COSV55381768; called by muse, mutect2, varscan2
- PPFIA2 | c.1821A>T p.G607= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as COSV61043697; called by muse, mutect2, varscan2
- TSGA13 | c.42A>C p.S14= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV63018983; called by muse, mutect2, varscan2
- ZNF189 | c.921A>G p.Q307= | Silent (SNP) | VAF 230/464 reads (50%) | catalogued as rs1372936047, COSV52276145; called by muse, mutect2, varscan2
- DFFB | c.242-117T>C | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as COSV58861232; called by muse, mutect2, varscan2
- YY1AP1 | c.*1G>A | 3'UTR (SNP) | VAF 151/376 reads (40%) | catalogued as COSV99803553; called by muse, mutect2, varscan2
- ZNF833P | n.1008T>A | RNA (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
